Somatic mutation profile of tumor specimen TCGA-24-1422-01A (aliquot TCGA-24-1422-01A-01W-0545-08) from TCGA case TCGA-24-1422, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 82.8 years (30,234 days).
Specimen TCGA-24-1422-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee614b45-85fa-4626-a808-77179c144986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1422-10A (Blood Derived Normal), aliquot TCGA-24-1422-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77e1480f-243c-48e5-b097-7bcf57329086

The open-access MAF lists 166 somatic variants for this specimen: 127 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 36, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 3, Splice Site 2, 3'UTR 1, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH7A1 | c.1301A>G p.Y434C | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747597620, COSV63160995; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNH2 | c.453dup p.T152Hfs*180 | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | catalogued as rs761863251; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 299/688 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.547); catalogued as COSV59608294; called by muse, mutect2, varscan2
- ACAD10 | c.629T>G p.F210C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58159970; called by muse, mutect2, varscan2
- ADAMTS17 | c.2865C>A p.C955* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | catalogued as COSV51475556, COSV99170777; called by muse, mutect2
- ADCY8 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99652611; called by muse, mutect2
- AGPAT3 | c.359T>A p.V120D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52367911, COSV52372368; called by muse, varscan2
- ALG10B | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 84/478 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV58144019; called by muse, mutect2, varscan2
- ATP11C | c.3396G>T p.L1132F | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59569153; called by muse, mutect2, varscan2
- C4BPA | c.1779G>T p.L593F | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100891224; called by muse, mutect2
- CARD6 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs762113942, COSV54567561, COSV54567611; called by muse, mutect2, varscan2
- CDKAL1 | c.1141G>C p.V381L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as COSV51186853; called by muse, mutect2, varscan2
- CFP | c.146dup p.G50Wfs*19 | Frame Shift Ins (INS) | VAF 5/54 reads (9%) | catalogued as rs749541242; called by pindel, varscan2
- CHD4 | c.1808G>A p.G603E (on ENST00000357008 / NM_001363606.2; = p.G616E on NM_001273.5) | Missense Mutation (SNP) | VAF 121/936 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58906443; called by muse, mutect2, varscan2
- CHST6 | c.746A>T p.H249L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM032877, CM091067, COSV60001085; called by muse, mutect2, varscan2
- CPA6 | c.527T>G p.I176S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV52736569; called by muse, varscan2
- CSMD2 | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV99591154; called by muse, mutect2, varscan2
- CSMD2 | c.2760T>G p.C920W | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591159, COSV99595787; called by muse, mutect2, varscan2
- DHX16 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV64564805; called by muse, mutect2, varscan2
- DIRAS1 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV60216290; called by muse, mutect2, varscan2
- DISC1 | c.428G>A p.W143* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99697898; called by muse, mutect2, varscan2
- DISP2 | c.2836T>C p.W946R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51130570; called by muse, mutect2, varscan2
- DNER | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs530602445, COSV59160424; called by muse, mutect2, varscan2
- EFCAB12 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 292/841 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.069); catalogued as COSV58177621; called by muse, mutect2
- EPB41L3 | c.2755A>G p.T919A | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV59461470; called by muse, mutect2, varscan2
- FAM135B | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV50532393; called by muse, mutect2, varscan2
- FASTKD2 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV52699321; called by muse, mutect2, varscan2
- FBXO15 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 100/188 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV54047024; called by muse, mutect2, varscan2
- FLT3 | c.2246C>G p.S749W | Missense Mutation (SNP) | VAF 20/740 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as COSV99609737; called by muse, mutect2
- FRMPD4 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 219/565 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as rs1294169574, COSV66213070; called by muse, mutect2, varscan2
- GGT7 | c.1317C>T p.L439= | Splice Region (SNP) | VAF 35/140 reads (25%) | catalogued as rs747409496, COSV60541799; called by muse, mutect2, varscan2
- GK2 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 14/429 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV100725974, COSV62627843; called by muse, mutect2
- GNAT3 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101242395; called by muse, mutect2
- IBTK | c.1858G>A p.V620I | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100090871; called by muse, mutect2, varscan2
- IFT122 | c.2302G>T p.V768L (on ENST00000348417 / NM_052989.3; = p.V709L on NM_018262.4) | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV56202308, COSV56205725, COSV56208976; called by muse, mutect2, varscan2
- ITIH3 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 271/469 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56256925; called by muse, mutect2, varscan2
- KIAA1614 | c.3182G>T p.R1061L | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV62551351; called by muse, mutect2, varscan2
- LAMA3 | c.6660T>A p.S2220R (on ENST00000313654 / NM_198129.4; = p.S611R on NM_000227.6) | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as COSV52538969; called by muse, mutect2, varscan2
- LCLAT1 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 395/838 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58375722; called by muse, mutect2, varscan2
- LCTL | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV58422633; called by muse, mutect2, varscan2
- LDHAL6B | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.302); catalogued as rs1480105782, COSV55691415; called by muse, mutect2, varscan2
- LPA | c.3361G>T p.V1121F | Missense Mutation (SNP) | VAF 92/580 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100307126; called by muse, varscan2
- LRP1 | c.7897G>A p.A2633T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757577718, COSV54518887; called by muse, mutect2, varscan2
- MAP4 | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 28/1078 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100805873; called by muse, mutect2
- MDH1B | c.173G>C p.S58T | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as COSV65590589; called by muse, mutect2, varscan2
- MNAT1 | c.793A>T p.M265L | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99710398; called by muse, mutect2, varscan2
- MUC16 | c.38770G>A p.D12924N | Missense Mutation (SNP) | VAF 460/2217 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.977); catalogued as COSV67479970; called by muse, varscan2
- NKAPD1 | c.821G>A p.R274H (on ENST00000280352 / NM_001082970.2; = p.R275H on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs201262827, COSV54777523; called by muse, mutect2, varscan2
- NRROS | c.1036G>C p.G346R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100145509; called by muse, mutect2, varscan2
- NSD1 | c.7259C>G p.P2420R | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV61780054; called by muse, mutect2, varscan2
- NXPE4 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV64944102; called by muse, mutect2, varscan2
- OR4A47 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 92/818 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101487041, COSV71444869; called by muse, varscan2
- OR5H1 | c.857A>T p.N286I | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63402940; called by muse, mutect2, varscan2
- PARP12 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753872576, COSV54935907; called by muse, mutect2, varscan2
- PBK | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.438); catalogued as COSV100107386; called by muse, mutect2
- PBXIP1 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100870092; called by muse, mutect2
- PCDHGA9 | c.550A>C p.T184P | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV99539647; called by muse, mutect2, varscan2
- PDCD2L | c.481C>G p.R161G | Missense Mutation (SNP) | VAF 131/344 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV55825917; called by muse, mutect2, varscan2
- PLEKHB2 | c.222C>G p.D74E | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52177022; called by muse, mutect2, varscan2
- PMPCB | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV50786764; called by muse, mutect2, varscan2
- PNMA1 | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV54096919; called by muse, mutect2, varscan2
- POSTN | c.1569G>C p.E523D | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV101123358; called by muse, mutect2
- POU6F1 | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 93/275 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV61327331; called by muse, mutect2, varscan2
- PRLHR | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53304504; called by muse, varscan2
- PSMD13 | c.490C>G p.Q164E | Missense Mutation (SNP) | VAF 111/474 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV61501464; called by muse, mutect2, varscan2
- PTPN21 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60850228; called by muse, mutect2, varscan2
- PTPRZ1 | c.1403A>T p.N468I | Missense Mutation (SNP) | VAF 101/465 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV66441750; called by muse, mutect2, varscan2
- RBM44 | c.454T>C p.W152R (on ENST00000611254; = p.W786R on NM_001080504.2) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57631797; called by muse, mutect2, varscan2
- RDH8 | c.139C>G p.H47D (on ENST00000651512; = p.H27D on NM_015725.4) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.098); catalogued as COSV50676312; called by muse, mutect2, varscan2
- RECQL5 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758403193, COSV100512039; called by muse, mutect2
- RP1 | c.3791T>A p.V1264E | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV55121671, COSV55121774; called by muse, mutect2, varscan2
- RWDD4 | c.300G>T p.L100F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58394215; called by muse, mutect2, varscan2
- RYR1 | c.5458C>T p.R1820C | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as rs767062679, COSV62092343; called by muse, mutect2, varscan2
- SEMA4C | c.1923C>G p.Y641* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV59691661; called by muse, mutect2
- SLC23A3 | c.727C>T p.H243Y (on ENST00000409878 / NM_001144889.2; = p.F232= on NM_144712.5) | Missense Mutation (SNP) | VAF 211/274 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99841183; called by mutect2, varscan2
- SLC35C1 | c.232T>G p.F78V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV58480518; called by muse, mutect2, varscan2
- SLC45A4 | c.964C>G p.P322A (on ENST00000517878 / NM_001286646.2; = p.P271A on NM_001080431.2) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV50150091; called by muse, mutect2, varscan2
- SMC2 | c.3215T>A p.V1072D | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961306; called by muse, mutect2
- SNRNP200 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 191/878 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60492363; called by muse, mutect2, varscan2
- SORBS2 | c.3134C>G p.P1045R (on ENST00000284776 / NM_021069.5; = p.P611R on NM_003603.6) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV99511264; called by mutect2, varscan2
- SORCS3 | c.3461A>T p.N1154I | Missense Mutation (SNP) | VAF 129/187 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63817672; called by muse, mutect2, varscan2
- SOX5 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.904); catalogued as rs751975537, COSV58638990; called by muse, mutect2, varscan2
- SPATA2 | c.1510A>C p.N504H | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as COSV56867523; called by muse, mutect2, varscan2
- SPNS3 | c.110G>T p.W37L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV100337025, COSV61069179; called by muse, mutect2, varscan2
- SPNS3 | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100337029; called by muse, mutect2, varscan2
- STARD4 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV56968577; called by muse, mutect2, varscan2
- SUCO | c.3390A>G p.I1130M | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs766681517, COSV55268540; called by muse, mutect2, varscan2
- TAC3 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55648532; called by muse, varscan2
- TAS2R46 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV67859454; called by muse, varscan2
- TBCK | c.1826G>C p.S609T (on ENST00000273980 / NM_001163436.4; = p.S546T on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV56759356; called by muse, mutect2, varscan2
- TIE1 | c.568A>T p.S190C | Missense Mutation (SNP) | VAF 94/610 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV65250509; called by muse, mutect2, varscan2
- TM9SF2 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV64507153; called by muse, mutect2, varscan2
- TMC3 | c.2531C>A p.T844K | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100845919; called by muse, mutect2
- TMPRSS15 | c.125C>A p.T42K | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV53044235; called by muse, mutect2, varscan2
- TNFAIP3 | c.1534C>G p.H512D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99396844; called by muse, mutect2
- TOP1 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 29/292 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV100793846; called by muse, mutect2
- TRAPPC8 | c.3479C>G p.A1160G | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as COSV51971750, COSV51974779; called by muse, mutect2, varscan2
- TRIM50 | c.1170G>C p.K390N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53092890; called by muse, mutect2
- TRIP12 | c.3841C>G p.Q1281E | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as COSV52268793; called by muse, mutect2, varscan2
- TRPV4 | c.610A>T p.N204Y | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV55683775; called by muse, mutect2, varscan2
- UBR3 | c.4423G>T p.A1475S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.052); catalogued as COSV55855267; called by muse, mutect2, varscan2
- UMPS | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV51738182; called by muse, mutect2, varscan2
- UNC5D | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 20/489 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.497); catalogued as COSV54769077, COSV99775938; called by muse, mutect2
- URGCP | c.412G>A p.V138M (on ENST00000453200 / NM_001077663.3; = p.V129M on NM_017920.4) | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs201075158, COSV56250303; called by muse, mutect2, varscan2
- USP24 | c.3080A>G p.E1027G | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV53773240; called by muse, mutect2, varscan2
- VPS13B | c.10588C>T p.R3530W | Missense Mutation (SNP) | VAF 183/671 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763017122, COSV62150324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VSIG10 | c.875C>A p.T292K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs76458716; called by mutect2, varscan2
- WNT7B | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as COSV59751340; called by muse, mutect2, varscan2
- XPC | c.2269G>C p.G757R | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53206391, COSV99542273; called by muse, mutect2, varscan2
- ZC3H13 | c.2522G>C p.R841P | Missense Mutation (SNP) | VAF 82/471 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99668266; called by muse, mutect2, varscan2
- ZMYM4 | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV58914136; called by muse, mutect2, varscan2
- ZNF250 | c.1306T>G p.S436A | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.18); catalogued as COSV52970012; called by muse, mutect2, varscan2
- ZNF385A | c.595C>T p.R199W (on ENST00000338010 / NM_001130967.3; = p.R179W on NM_015481.3) | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1184015946, COSV61493038; called by muse, mutect2, varscan2
- ZNF74 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759399320, COSV62622318; called by muse, mutect2, varscan2
- ZSWIM8 | c.3115A>T p.R1039W (on ENST00000605216 / NM_001242487.2; = p.R1044W on NM_015037.3) | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV67133605; called by muse, mutect2, varscan2
- AGPAT3 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, varscan2
- CEP250 | c.2855G>T p.R952M | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GCLC | c.626-5_632del p.X209_splice (on ENST00000643939; = p.X207_splice on NM_001498.4) | Splice Site (DEL) | VAF 24/158 reads (15%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.401A>T p.K134M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- HSPB9 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LMO7 | c.321+2dup p.X107_splice (on ENST00000357063; = p.X122_splice on NM_005358.5) | Splice Site (INS) | VAF 28/101 reads (28%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.3872_3899del p.L1291Qfs*13 | Frame Shift Del (DEL) | VAF 45/294 reads (15%) | called by mutect2, pindel
- PRAMEF20 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 95/3122 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.35); called by muse, mutect2
- RAPGEF1 | c.1839dup p.K614Qfs*34 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by pindel, varscan2
- RIN2 | c.1699_1721delinsG p.I567Dfs*8 (on ENST00000255006 / NM_001242581.1; = p.I518Dfs*8 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 44/165 reads (27%) | called by pindel, varscan2*
- TRA2B | c.498del p.F166Lfs*4 | Frame Shift Del (DEL) | VAF 44/105 reads (42%) | called by mutect2, pindel, varscan2
- AGPAT3 | c.360C>T p.V120= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, varscan2
- AP4B1 | c.1536G>T p.R512= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV56726001; called by muse, mutect2, varscan2
- C10orf71 | c.369G>A p.Q123= | Silent (SNP) | VAF 49/311 reads (16%) | catalogued as COSV60510292, COSV60512610; called by muse, mutect2, varscan2
- CLIC1 | c.12A>G p.E4= | Silent (SNP) | VAF 143/727 reads (20%) | catalogued as COSV65210542; called by muse, mutect2, varscan2
- CTCFL | c.462C>T p.H154= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as rs142548833, COSV99712828; called by muse, mutect2
- CYCS | c.261G>A p.K87= | Silent (SNP) | VAF 50/282 reads (18%) | catalogued as COSV59872780; called by muse, mutect2, varscan2
- EYA2 | c.810G>C p.V270= | Silent (SNP) | VAF 266/1792 reads (15%) | catalogued as COSV57947487; called by muse, mutect2, varscan2
- FAM83B | c.1230T>C p.N410= | Silent (SNP) | VAF 62/318 reads (19%) | catalogued as COSV60924548; called by muse, mutect2, varscan2
- FAM83B | c.2469A>G p.K823= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV60924556; called by muse, mutect2, varscan2
- FAM83C | c.2022C>A p.T674= | Silent (SNP) | VAF 36/290 reads (12%) | catalogued as COSV65583771; called by muse, mutect2, varscan2
- H3C8 | c.141G>A p.V47= | Silent (SNP) | VAF 31/264 reads (12%) | catalogued as COSV59953400; called by muse, mutect2, varscan2
- HYDIN | c.3735A>G p.A1245= | Silent (SNP) | VAF 150/283 reads (53%) | catalogued as COSV66833442; called by muse, mutect2, varscan2
- IBTK | c.1857G>T p.V619= | Silent (SNP) | VAF 26/215 reads (12%) | catalogued as COSV60394719; called by muse, mutect2, varscan2
- ITGAD | c.1563G>T p.G521= | Silent (SNP) | VAF 85/2396 reads (4%) | catalogued as COSV101210505, COSV101210628; called by muse, mutect2
- KANK4 | c.252A>G p.A84= | Silent (SNP) | VAF 59/402 reads (15%) | catalogued as COSV62987969, COSV62989237; called by muse, mutect2, varscan2
- KIAA1109 | c.13734A>G p.E4578= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV52683670; called by muse, mutect2, varscan2
- LYPD1 | c.414G>C p.S138= | Silent (SNP) | VAF 66/218 reads (30%) | catalogued as COSV100257870; called by muse, mutect2, varscan2
- NDC80 | c.1599G>A p.E533= | Silent (SNP) | VAF 27/203 reads (13%) | catalogued as COSV55248928, COSV99859658; called by muse, mutect2, varscan2
- NRCAM | c.2910G>A p.L970= (on ENST00000379028 / NM_001371124.1; = p.L954= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 50/327 reads (15%) | catalogued as COSV61043298; called by muse, mutect2, varscan2
- NRROS | c.1935G>T p.R645= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV60746875; called by muse, mutect2, varscan2
- OR2A5 | c.543C>T p.I181= | Silent (SNP) | VAF 122/922 reads (13%) | catalogued as rs753278713, COSV68738944; called by muse, mutect2, varscan2
- PCDHA2 | c.432A>G p.E144= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV65369250; called by muse, mutect2, varscan2
- PCDHB6 | c.1644G>A p.L548= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs782699434, COSV50709332; called by muse, mutect2, varscan2
- PLEKHG4B | c.3634C>T p.L1212= (on ENST00000283426; = p.L1568= on NM_052909.5) | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV99360417; called by muse, mutect2
- RBPJL | c.594G>A p.K198= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as rs1251454297, COSV100637057; called by muse, mutect2
- RNF186 | c.121C>T p.L41= | Silent (SNP) | VAF 10/285 reads (4%) | called by muse, mutect2
- SLC23A3 | c.726T>C p.F242= (on ENST00000409878 / NM_001144889.2; = p.F232S on NM_144712.5) | Silent (SNP) | VAF 172/234 reads (74%) | catalogued as COSV99841186; called by mutect2, varscan2
- SLC33A1 | c.846C>T p.N282= | Silent (SNP) | VAF 77/225 reads (34%) | catalogued as rs1341440565, COSV63946688; called by muse, mutect2, varscan2
- SLC4A8 | c.2001G>T p.L667= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV60655902; called by muse, mutect2, varscan2
- TG | c.2676T>C p.H892= | Silent (SNP) | VAF 32/218 reads (15%) | catalogued as COSV55086554; called by muse, mutect2, varscan2
- TRAPPC12 | c.156G>A p.S52= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs145615349; called by muse, mutect2, varscan2
- TTC27 | c.1477C>T p.L493= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV100513144, COSV100513803; called by muse, mutect2
- TTN | c.73083T>C p.I24361= (on ENST00000591111; = p.I16937= on NM_003319.4) | Silent (SNP) | VAF 178/471 reads (38%) | catalogued as COSV100616375; called by muse, varscan2
- USP5 | c.1299G>A p.Q433= | Silent (SNP) | VAF 39/386 reads (10%) | called by mutect2, varscan2
- ZNF132 | c.441T>C p.C147= | Silent (SNP) | VAF 32/379 reads (8%) | catalogued as COSV99571193; called by muse, mutect2
- ZNF292 | c.1671A>G p.V557= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV60542495; called by muse, mutect2, varscan2
- FGF10 | c.*2G>A | 3'UTR (SNP) | VAF 88/266 reads (33%) | catalogued as rs201327715, COSV99240665; called by muse, mutect2, varscan2
- OR52A4P | n.893C>G | RNA (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796173 G>C | 5'Flank (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
